Somatic mutation profile of tumor specimen TCGA-04-1646-01A (aliquot TCGA-04-1646-01A-01W-0639-09) from TCGA case TCGA-04-1646, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 60.8 years (22,207 days).
Specimen TCGA-04-1646-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8705baf4-3be7-483a-9b65-f08d4f9efbad.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-04-1646-11A (Solid Tissue Normal), aliquot TCGA-04-1646-11A-01W-0639-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8c4d3c29-8385-49ee-bf7e-cf3eece793ac

The open-access MAF lists 24 somatic variants for this specimen: 18 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 5, Splice Region 1, Intron 1, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALPI | c.398C>A p.A133E | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV55013987; called by muse, mutect2, varscan2
- CACNB1 | c.961C>G p.L321V | Missense Mutation (SNP) | VAF 83/90 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1445215067, COSV59998402; called by muse, mutect2, varscan2
- CLPTM1 | c.1158G>C p.Q386H | Missense Mutation (SNP) | VAF 40/136 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.369); catalogued as COSV61611491; called by muse, mutect2, varscan2
- ERMARD | c.1914G>C p.K638N | Missense Mutation (SNP) | VAF 222/246 reads (90%) | SIFT deleterious (0); PolyPhen possibly damaging (0.544); catalogued as COSV64647857; called by muse, varscan2
- EWSR1 | c.1615G>T p.E539* | Nonsense Mutation (SNP) | VAF 13/371 reads (4%) | catalogued as COSV100131274, COSV58425415; called by muse, mutect2
- FLCN | c.498C>A p.F166L | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (0.56); PolyPhen benign (0.078); catalogued as COSV99550285; called by muse, mutect2
- INCENP | c.1813C>A p.Q605K (on ENST00000394818 / NM_001040694.2; = p.Q601K on NM_020238.3) | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.679); catalogued as COSV53915628, COSV53917927, COSV99610877; called by muse, mutect2
- KIT | c.1910T>A p.L637H | Missense Mutation (SNP) | VAF 164/368 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55394157; called by muse, mutect2, varscan2
- KLF1 | c.932G>A p.C311Y | Missense Mutation (SNP) | VAF 32/48 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53434704; called by muse, mutect2, varscan2
- MAST2 | c.3871G>A p.G1291R | Missense Mutation (SNP) | VAF 36/105 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.439); catalogued as COSV63617207; called by muse, mutect2, varscan2
- NCOA6 | c.2303C>T p.P768L | Missense Mutation (SNP) | VAF 189/565 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.039); catalogued as COSV62862377; called by muse, mutect2, varscan2
- SCN1A | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 266/522 reads (51%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.959); catalogued as rs769582667, COSV57660030; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SDHC | c.19A>C p.R7= | Splice Region (SNP) | VAF 69/244 reads (28%) | catalogued as COSV60667978; called by muse, mutect2, varscan2
- STYXL2 | c.703C>A p.L235M | Missense Mutation (SNP) | VAF 8/212 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99608970; called by muse, mutect2
- TM9SF4 | c.112G>A p.D38N | Missense Mutation (SNP) | VAF 202/620 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.195); catalogued as rs1427203667, COSV54104402; called by muse, varscan2
- VPS13C | c.2982G>T p.E994D (on ENST00000644861 / NM_020821.3; = p.E951D on NM_017684.5) | Missense Mutation (SNP) | VAF 41/110 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as rs748343915, COSV51136507; called by muse, mutect2, varscan2
- WDR62 | c.3397G>A p.G1133R | Missense Mutation (SNP) | VAF 59/111 reads (53%) | SIFT tolerated (0.14); PolyPhen benign (0.041); catalogued as rs750117864, COSV54332316; called by muse, mutect2, varscan2
- HSPA8 | c.998_1008del p.D333Gfs*25 | Frame Shift Del (DEL) | VAF 64/146 reads (44%) | called by mutect2, pindel, varscan2
- FOXP3 | c.495G>A p.P165= | Silent (SNP) | VAF 59/62 reads (95%) | catalogued as rs781920028, COSV66051040; ClinVar: benign; called by muse, mutect2, varscan2
- KMT2D | c.11019T>A p.L3673= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as COSV56423317; called by muse, mutect2, varscan2
- SEC16A | c.4761G>A p.V1587= | Silent (SNP) | VAF 5/39 reads (13%) | catalogued as COSV99257279; called by muse, mutect2
- SHROOM3 | c.4626C>T p.S1542= | Silent (SNP) | VAF 72/125 reads (58%) | catalogued as COSV56025680; called by muse, mutect2, varscan2
- TSC2 | c.4929C>T p.N1643= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as rs45517381, CM971529; ClinVar: benign / likely benign; called by muse, mutect2
- FKBP1B | c.199-22C>A | Intron (SNP) | VAF 54/586 reads (9%) | catalogued as COSV99272690; called by muse, mutect2
